Somatic mutation profile of tumor specimen MMRF_2698_1_BM_CD138pos (aliquot MMRF_2698_1_BM_CD138pos_T1_KHS5U_L14424) from MMRF case MMRF_2698, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,616 days).
Specimen MMRF_2698_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8595b38-9dc7-4698-922a-27a5e1270f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2698_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2698_1_PB_WBC_C2_KHS5U_L14425; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65caa41-1e29-41f5-8abb-37fe654e1921

The open-access MAF lists 113 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 37, Missense Mutation 32, Intron 17, Silent 9, Frame Shift Del 5, RNA 3, Splice Site 2, Nonsense Mutation 2, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.2118G>T p.L706F | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs751930088; called by muse, mutect2, varscan2
- CSMD3 | c.10517A>G p.N3506S (on ENST00000297405 / NM_001363185.1; = p.N3337S on NM_052900.3) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1349192994; called by muse, mutect2, varscan2
- ERCC6 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63391846, COSV63392254; called by muse, mutect2, varscan2
- H2AC17 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs191325870, COSV58152870; called by muse, mutect2, varscan2
- LMF1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs759097865; called by muse, mutect2, varscan2
- PCDH10 | c.1876A>C p.M626L | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52089840; called by muse, mutect2, varscan2
- PPARGC1A | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); catalogued as COSV53531924; called by muse, mutect2, varscan2
- PRPF31 | c.1149C>A p.I383= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100320076; called by muse, mutect2, varscan2
- RNF43 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs775363695; called by muse, mutect2, varscan2
- TRRAP | c.9775C>T p.R3259C (on ENST00000359863 / NM_001244580.1; = p.R3230C on NM_003496.3) | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62845374; called by muse, mutect2, varscan2
- AFDN | c.1769+1G>T p.X590_splice | Splice Site (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- AKR1B1 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- ANK2 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CDR2 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 72/258 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNIH2 | c.76T>G p.W26G | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CTRB2 | c.81_94del p.L28Qfs*58 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- CYP7B1 | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF6 | c.1673A>G p.N558S (on ENST00000312263 / NM_001349778.1; = p.N578S on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCLRE1A | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DENND4B | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by mutect2, varscan2
- DISP1 | c.1966G>T p.V656F | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- DMRT3 | c.1145G>T p.S382I | Missense Mutation (SNP) | VAF 84/355 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GLRX3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GPR20 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HIVEP1 | c.5605C>T p.L1869F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKJ3 | c.16del p.T8Pfs*? | Frame Shift Del (DEL) | VAF 77/217 reads (35%) | called by pindel, varscan2
- KAT6A | c.702dup p.N235Qfs*13 | Frame Shift Ins (INS) | VAF 53/123 reads (43%) | called by mutect2, pindel, varscan2
- LINGO1 | c.593del p.L198Rfs*6 | Frame Shift Del (DEL) | VAF 48/235 reads (20%) | called by mutect2, varscan2
- MOB3B | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- MRTO4 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NT5E | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRF1 | c.1145T>A p.M382K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RELN | c.5366T>G p.F1789C | Missense Mutation (SNP) | VAF 10/340 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RRBP1 | c.3582G>T p.V1194= (on ENST00000377813 / NM_001365613.2; = p.V761= on NM_004587.3) | Splice Region (SNP) | VAF 66/202 reads (33%) | called by muse, mutect2, varscan2
- S100A4 | c.144A>C p.K48N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SEC14L1 | c.377_382delinsCG p.F126Sfs*6 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by pindel, varscan2*
- SLC12A7 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- SPARCL1 | c.1977T>G p.D659E | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SYCP2 | c.2342G>A p.W781* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2
- THBD | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRAF3 | c.297+1G>A p.X99_splice | Splice Site (SNP) | VAF 86/150 reads (57%) | called by muse, mutect2, varscan2
- VWDE | c.2809G>T p.V937F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ZDHHC17 | c.302_309del p.N101Rfs*51 | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | called by mutect2, pindel, varscan2
- ZNF18 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZPR1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.1314A>G p.R438= | Silent (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- ERAP1 | c.1428G>A p.E476= | Silent (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- FOXC2 | c.723G>A p.P241= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1300393594; called by muse, mutect2, varscan2
- IGSF6 | c.159C>T p.F53= | Silent (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- IL1R2 | c.1156C>T p.L386= | Silent (SNP) | VAF 56/207 reads (27%) | called by muse, mutect2, varscan2
- NUTM2G | c.408C>A p.T136= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- OR10G3 | c.96T>C p.F32= | Silent (SNP) | VAF 25/228 reads (11%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1101G>T p.L367= | Silent (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ZNF267 | c.318T>C p.C106= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV56252285; called by muse, mutect2, varscan2
- ABLIM3 | c.*1536G>C | 3'UTR (SNP) | VAF 37/93 reads (40%) | catalogued as rs929925462; called by muse, mutect2, varscan2
- ADAMTS5 | c.*1833T>C | 3'UTR (SNP) | VAF 43/68 reads (63%) | called by muse, mutect2, varscan2
- AHCTF1P1 | n.6170A>G | RNA (SNP) | VAF 56/216 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.*1724T>C | 3'UTR (SNP) | VAF 5/85 reads (6%) | catalogued as rs890834471; called by muse, mutect2
- ARL13A | c.*268C>T | 3'UTR (SNP) | VAF 53/210 reads (25%) | catalogued as rs764135914; called by muse, mutect2, varscan2
- ARMC10P1 | n.830T>A | RNA (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- ASB5 | c.*1646A>T | 3'UTR (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- CCSER1 | c.*665C>T | 3'UTR (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- CDH6 | c.*4765G>A | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*5757T>C | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- DCDC2 | c.*620C>T | 3'UTR (SNP) | VAF 38/117 reads (32%) | catalogued as rs910511859; called by muse, mutect2, varscan2
- DSC2 | c.*240T>C | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*585A>G | 3'UTR (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- FADS2 | c.619-1190A>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- FAM110C | c.*1212C>T | 3'UTR (SNP) | VAF 63/136 reads (46%) | catalogued as rs1266405479; called by muse, mutect2, varscan2
- FAM205A | c.*38T>A | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- FBXL7 | c.*956G>T | 3'UTR (SNP) | VAF 53/228 reads (23%) | called by muse, mutect2, varscan2
- FGA | c.1891+146del | Intron (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- FOXN4 | c.*341C>A | 3'UTR (SNP) | VAF 50/159 reads (31%) | called by muse, mutect2, varscan2
- FRMD5 | c.*271A>G | 3'UTR (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2
- FXR1 | c.52-5683_52-5674del | Intron (DEL) | VAF 35/215 reads (16%) | called by mutect2, pindel, varscan2
- GLRA3 | c.*2036T>C | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- GPRC5B | c.*1827G>T | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- GUCY2D | c.2576+43G>C | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GULP1 | c.843+1352G>C | Intron (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+19597A>G | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- KRT82 | c.*440C>T | 3'UTR (SNP) | VAF 28/102 reads (27%) | catalogued as rs987763721; called by muse, mutect2
- LRATD1 | c.*4361G>C | 3'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4362C>T | 3'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- LRRC7 | c.647+36109G>A | Intron (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- METAP2 | c.326-1066A>G | Intron (SNP) | VAF 89/279 reads (32%) | called by muse, mutect2, varscan2
- MORC2 | c.3031-177C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs1039579045; called by muse, mutect2, varscan2
- NCAM2 | c.*3480T>G | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- NR4A1 | c.160+3588G>C | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2
- NRARP | c.*1714C>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- OSR2 | c.-114-583C>T | Intron (SNP) | VAF 63/176 reads (36%) | called by muse, mutect2, varscan2
- OTULINL | c.*998T>C | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, varscan2
- PABPC5 | c.*400C>T | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- PRLR | c.*3816C>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | catalogued as rs1194596867; called by muse, mutect2, varscan2
- PRR18 | chr6:166308406 G>T | 5'Flank (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2
- PSD3 | c.*4915A>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- PTCD3 | c.1778+16C>T | Intron (SNP) | VAF 24/90 reads (27%) | catalogued as rs772762873; called by muse, mutect2, varscan2
- RAB6B | c.*1386C>T | 3'UTR (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.*1608G>A | 3'UTR (SNP) | VAF 25/243 reads (10%) | called by muse, mutect2
- RNASE9 | c.-14-1178G>A | Intron (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1446T>C | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143624741 T>A | 3'Flank (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- SRD5A3 | c.*568G>A | 3'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs1366524738; called by muse, mutect2, varscan2
- SRPX | c.*198T>A | 3'UTR (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.*52C>T | 3'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- STRCP1 | n.3629A>C | RNA (SNP) | VAF 19/108 reads (18%) | called by mutect2, varscan2
- TIPARP | c.*829T>G | 3'UTR (SNP) | VAF 37/118 reads (31%) | called by muse, varscan2
- TMCC3 | c.*2768C>A | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2
- TTC6 | c.1201-3924G>T | Intron (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- UBQLN1 | c.*39G>A | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+1246T>G | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- ZNF155 | c.15+44T>C | Intron (SNP) | VAF 97/202 reads (48%) | called by muse, mutect2, varscan2
- ZNF26 | c.*182A>G | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- ZNF783 | c.674-163A>G | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
